Somatic mutation profile of tumor specimen C3N-01012-01 (aliquot CPT0241320008) from CPTAC case C3N-01012, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.1 years (25,953 days).
Specimen C3N-01012-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42d6452b-1008-473b-a270-7f527a66dc8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01012-30 (Blood Derived Normal), aliquot CPT0241740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09bd94aa-65a0-41d4-a39a-fe3424ddb601

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 124/1368 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 34/884 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2
- COL6A3 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143819673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs556779874, COSV52331561, COSV52347321, COSV99306180; called by muse, mutect2
- EPS15L1 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as COSV50176692; called by muse, mutect2
- ERBB4 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 36/712 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1463950609, COSV53593488; called by muse, mutect2
- FBN3 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 74/760 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs375756610; called by muse, mutect2
- GOLGA6L7 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 60/1176 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs763513868, COSV101629716; called by muse, mutect2
- HAS1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs554437003, COSV99708421; called by muse, mutect2
- KIF5B | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192602; called by muse, mutect2
- LYST | c.4687C>T p.R1563C | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs749045467, COSV67710457; called by muse, mutect2
- P2RX4 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 56/732 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327325791; called by muse, mutect2
- PRDM9 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 45/990 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1299187030, COSV57013972; called by muse, mutect2
- SSC5D | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1438021263; called by muse, mutect2
- VPS13B | c.1735A>G p.I579V | Missense Mutation (SNP) | VAF 39/419 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750419805, COSV100662337; called by muse, mutect2
- CHRM2 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPB2 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2
- FGD6 | c.3905G>A p.S1302N | Missense Mutation (SNP) | VAF 21/353 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2
- JUNB | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 85/895 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYLK4 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2
- PCDH19 | c.2345G>T p.S782I (on ENST00000373034 / NM_001184880.2; = p.S735I on NM_020766.3) | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RPS6KB1 | c.689-2A>C p.X230_splice | Splice Site (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- ASTL | c.513G>A p.T171= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as rs778436747; called by muse, mutect2
- C2orf81 | c.1504C>T p.L502= | Silent (SNP) | VAF 33/281 reads (12%) | catalogued as rs965251194; called by muse, mutect2, varscan2
- CSMD3 | c.9603A>G p.P3201= (on ENST00000297405 / NM_001363185.1; = p.P3032= on NM_052900.3) | Silent (SNP) | VAF 36/684 reads (5%) | called by muse, mutect2
- KLHL18 | c.471C>T p.D157= | Silent (SNP) | VAF 48/928 reads (5%) | catalogued as rs147334917; called by muse, mutect2
- MAGEC1 | c.2634T>C p.Y878= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as COSV53582181; called by muse, mutect2, varscan2
- MYH15 | c.1731G>A p.K577= | Silent (SNP) | VAF 22/311 reads (7%) | called by muse, mutect2
- NFASC | c.327G>A p.P109= (on ENST00000339876 / NM_001378329.1; = p.P103= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/574 reads (6%) | catalogued as rs202239718; called by muse, mutect2
- NOTCH1 | c.6273T>C p.D2091= | Silent (SNP) | VAF 38/428 reads (9%) | catalogued as COSV53101518; called by muse, mutect2
- PCDHB2 | c.1347C>T p.N449= | Silent (SNP) | VAF 64/1504 reads (4%) | catalogued as rs781943142, COSV50622182; called by muse, mutect2
- TMEM132E | chr17:34579232 C>G | 5'Flank (SNP) | VAF 21/330 reads (6%) | catalogued as rs377334422; called by muse, mutect2
